Somatic mutation profile of tumor specimen TCGA-OR-A5J5-01A (aliquot TCGA-OR-A5J5-01A-11D-A29I-10) from TCGA case TCGA-OR-A5J5, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 30.6 years (11,171 days).
Specimen TCGA-OR-A5J5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e83dbdf-257c-48bf-8d0d-a510126a1843.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J5-10A (Blood Derived Normal), aliquot TCGA-OR-A5J5-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76dbed00-98fe-4323-9cdd-1ac9b8ed004e

The open-access MAF lists 368 somatic variants for this specimen: 260 protein-altering or splice-affecting, 99 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 213, Silent 99, Frame Shift Del 25, Nonsense Mutation 12, Intron 4, Splice Region 4, Frame Shift Ins 4, 3'UTR 2, 5'UTR 1, In Frame Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMPRSS6 | c.1786del p.A596Pfs*8 | Frame Shift Del (DEL) | VAF 97/147 reads (66%) | catalogued as rs767094129, CD082210; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 66/71 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 104/120 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141485184, COSV100045122, COSV59609071; called by muse, mutect2, varscan2
- ACTN1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770793826; called by muse, mutect2, varscan2
- ADAM12 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.439); catalogued as rs761670828; called by mutect2, varscan2
- ADAMTS16 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs1158314132, COSV56995148; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs559596593; called by muse, mutect2, varscan2
- ADPRM | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs768927768; called by muse, mutect2, varscan2
- ADRA2C | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV57467938; called by muse, mutect2, varscan2
- AHNAK | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs201304148; called by muse, mutect2, varscan2
- ANO2 | c.1853G>A p.R618H (on ENST00000356134 / NM_001278597.3; = p.R622H on NM_001278596.3) | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as rs373395051, COSV59049533; called by muse, mutect2, varscan2
- ARAP3 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53349126; called by muse, mutect2, varscan2
- ARHGEF11 | c.4070C>T p.T1357M | Missense Mutation (SNP) | VAF 100/114 reads (88%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.333); catalogued as rs141649554; called by muse, mutect2, varscan2
- ATP2B3 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs373144811, COSV54848526; called by muse, mutect2, varscan2
- B3GALT5 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as rs144752439; called by muse, mutect2, varscan2
- BAZ1A | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.474); catalogued as rs545004797, COSV62410801; called by muse, mutect2, varscan2
- BEND3 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64680264; called by muse, mutect2
- BLVRA | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138715080; called by muse, mutect2, varscan2
- BMS1 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 6/67 reads (9%) | catalogued as rs749025521; called by muse, mutect2, varscan2
- BNC2 | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 64/68 reads (94%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as rs752551063; called by muse, mutect2, varscan2
- BOP1 | c.106dup p.L36Pfs*34 | Frame Shift Ins (INS) | VAF 26/102 reads (25%) | catalogued as rs782133829; called by mutect2, varscan2
- BSN | c.7186C>T p.R2396W | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs774693300; called by muse, mutect2, varscan2
- C20orf27 | c.475G>A p.A159T (on ENST00000379772 / NM_001258429.2; = p.A184T on NM_001039140.3) | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs747293739, COSV53923679; called by muse, mutect2, varscan2
- C9orf43 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 143/153 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs369075240, COSV99928103; called by muse, mutect2, varscan2
- CACNA2D1 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as rs377337212; called by muse, mutect2, varscan2
- CACNA2D4 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs756285159, COSV54954128; called by muse, mutect2, varscan2
- CALHM1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375270464; called by muse, mutect2, varscan2
- CAMSAP1 | c.1161dup p.V388Rfs*19 | Frame Shift Ins (INS) | VAF 18/177 reads (10%) | catalogued as rs750552002; called by mutect2, pindel
- CAVIN2 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100414232; called by muse, mutect2, varscan2
- CHRD | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as rs201032668; called by muse, mutect2, varscan2
- CLEC4A | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as rs200191238, COSV57562797; called by muse, mutect2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 73/122 reads (60%) | catalogued as rs369752219; called by mutect2, varscan2
- CNTNAP1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1461856215; called by muse, mutect2, varscan2
- COL23A1 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010632914; called by muse, mutect2, varscan2
- COL5A2 | c.4357C>T p.R1453W | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs760569641, COSV66415837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLGALT1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs1002620025; called by muse, mutect2, varscan2
- CPSF1 | c.3028C>A p.P1010T | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV100450794; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 51/72 reads (71%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRISP2 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 143/155 reads (92%) | SIFT tolerated (0.49); PolyPhen benign (0.057); catalogued as COSV59255260; called by muse, mutect2, varscan2
- CRMP1 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 31/356 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs142255876; called by muse, mutect2
- CRY2 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs761601046; called by muse, mutect2, varscan2
- CSF1R | c.2335G>A p.V779M | Missense Mutation (SNP) | VAF 100/374 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768825118; called by muse, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 33/56 reads (59%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD1 | c.1226C>T p.A409V (on ENST00000520002; = p.A408V on NM_033225.6) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.914); catalogued as rs912861753; called by muse, mutect2, varscan2
- CXCR5 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as rs377218103; called by muse, mutect2, varscan2
- CYTH1 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs765492162, COSV63119649; called by muse, mutect2, varscan2
- DAAM2 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 62/71 reads (87%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as rs762963954, COSV51302392; called by muse, mutect2, varscan2
- DHODH | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563071819, COSV54661208; called by muse, mutect2, varscan2
- DPPA5 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100951539; called by muse, mutect2, varscan2
- DROSHA | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs1485879154, COSV100757815; called by muse, mutect2, varscan2
- DZANK1 | c.653G>A p.R218Q (on ENST00000262547 / NM_001099407.1; = p.R19Q on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/195 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs991448164; called by muse, mutect2, varscan2
- ELOVL7 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs755383949; called by muse, mutect2, varscan2
- EPB41L4B | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs750888890; called by muse, mutect2, varscan2
- EPG5 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs745425455, COSV99956259; called by muse, mutect2, varscan2
- ETV5 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 158/179 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV60506181; called by muse, mutect2, varscan2
- FAM135B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335175102, COSV104372835; called by muse, mutect2
- FAM13A | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs748582424; called by muse, mutect2, varscan2
- FBXO40 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 78/95 reads (82%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs143415272; called by muse, mutect2, varscan2
- FIZ1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 118/269 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99684593; called by muse, mutect2, varscan2
- FKBP8 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); catalogued as rs1178842404; called by muse, mutect2, varscan2
- FKRP | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59359094; called by muse, mutect2, varscan2
- FNIP1 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 197/381 reads (52%) | catalogued as COSV100330576; called by muse, mutect2, varscan2
- FOXK1 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as rs1299148388, COSV61064157; called by muse, mutect2, varscan2
- FSHR | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 79/90 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58628271; called by muse, mutect2, varscan2
- GFM2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs139234343; called by muse, mutect2, varscan2
- GLI2 | c.2107C>T p.R703C (on ENST00000361492 / NM_001374353.1; = p.R720C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/229 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs773976966, COSV100083906; called by muse, mutect2, varscan2
- GPR84 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 236/490 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758161369; called by muse, mutect2, varscan2
- GRHPR | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 105/113 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs747664983; called by muse, mutect2, varscan2
- GRIN2C | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751104229; called by muse, mutect2, varscan2
- GRM3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV64471156; called by muse, mutect2, varscan2
- GSAP | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773644663; called by muse, mutect2, varscan2
- GSTK1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 68/100 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs768336329, COSV64424422; called by muse, mutect2, varscan2
- HNRNPDL | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs755056939; called by muse, mutect2, varscan2
- HTR5A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs780790670, COSV55282302, COSV55284114; called by muse, mutect2, varscan2
- IL17C | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs758013472; called by muse, varscan2
- IL20RB | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs755597823; called by muse, mutect2, varscan2
- ILRUN | c.886G>A p.G296S (on ENST00000374023 / NM_024294.4; = p.G230S on NM_022758.6) | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.843); catalogued as rs375408800; called by muse, mutect2, varscan2
- ITIH2 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 49/83 reads (59%) | catalogued as rs545967088, COSV64433717; called by muse, mutect2, varscan2
- KANK1 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.605); catalogued as rs776859009, COSV63215519; called by muse, mutect2
- KCNH7 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV59789456, COSV59792787; called by muse, mutect2
- KDF1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57671426; called by muse, mutect2
- KDR | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 132/257 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs941528100, COSV55757975; called by muse, mutect2, varscan2
- KIF24 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776926178, COSV61454838; called by muse, mutect2, varscan2
- KLC3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs190310418; called by muse, mutect2, varscan2
- KMT2B | c.5554G>A p.A1852T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as rs746346674, COSV55859907; ClinVar: benign; called by muse, mutect2, varscan2
- KRT32 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs758366433; called by muse, mutect2, varscan2
- KRT33B | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 94/97 reads (97%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs778770978, COSV52441991; called by muse, mutect2, varscan2
- LACTB | c.1541del p.P514Qfs*22 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | catalogued as rs1566994708; called by mutect2, pindel, varscan2
- LILRB1 | c.1112C>T p.T371M (on ENST00000427581; = p.T335M on NM_006669.6) | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs374617117, COSV61116922; called by muse, mutect2, varscan2
- LMBRD1 | c.868G>A p.A290T (on ENST00000649011; = p.A268T on NM_018368.4) | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs143758103, COSV65299886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRGUK | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1045231026; called by muse, mutect2, varscan2
- LRRIQ1 | c.4733G>A p.R1578H | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs775269203; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs773841501, COSV61009934; called by muse, mutect2, varscan2
- MAP3K1 | c.4525C>T p.R1509C | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs769426596, COSV68127346; called by muse, mutect2, varscan2
- MAP7D3 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs764678376; called by muse, mutect2, varscan2
- MDGA1 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs754161882; called by muse, mutect2, varscan2
- MDH1B | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs780661298, COSV65590123; called by muse, mutect2, varscan2
- MOV10 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 86/100 reads (86%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs112768939; called by muse, mutect2, varscan2
- MUC16 | c.32477C>T p.T10826M | Missense Mutation (SNP) | VAF 88/391 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as rs759594403, COSV67496608; called by muse, mutect2, varscan2
- MYO1A | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141039063; called by muse, varscan2
- MYO9B | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1488588943, COSV101261829; called by muse, mutect2, varscan2
- NAV2 | c.4603C>T p.R1535W (on ENST00000396087 / NM_001244963.2; = p.R1512W on NM_145117.5) | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372406009; called by muse, mutect2, varscan2
- NCAN | c.3858C>A p.H1286Q | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV53052209; called by muse, mutect2, varscan2
- NLN | c.2069C>A p.P690Q | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66765833; called by muse, mutect2, varscan2
- NLRP12 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs766308091, COSV60757158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH3 | c.5551C>T p.R1851C | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376590511; called by muse, mutect2, varscan2
- NR2C2 | c.1033G>A p.V345I (on ENST00000393102; = p.V364I on NM_003298.5) | Missense Mutation (SNP) | VAF 149/166 reads (90%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs561716347, COSV60147405; called by muse, mutect2, varscan2
- NR4A2 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs1403697315, COSV59894654; called by muse, mutect2
- NSD1 | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 35/456 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs775044010; called by muse, mutect2
- NXF1 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs763128808, COSV53673685; called by muse, mutect2, varscan2
- OAS2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs143746502; called by muse, varscan2
- PCDH15 | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143538460, CM165389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA3 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 92/417 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.607); catalogued as rs1554122041, COSV63540260; called by muse, mutect2, varscan2
- PCDHB12 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.583); catalogued as COSV53396886; called by muse, mutect2, varscan2
- PDCD11 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 171/267 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs370752421; called by muse, mutect2, varscan2
- PDCD11 | c.3238A>G p.T1080A | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1197724406; called by muse, mutect2
- PDPR | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755313163, COSV55351269; called by muse, mutect2, varscan2
- PDYN | c.612C>A p.Y204* | Nonsense Mutation (SNP) | VAF 74/79 reads (94%) | catalogued as rs752659908; called by muse, mutect2, varscan2
- PDZD4 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 101/199 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs782693675, COSV51250529, COSV99381322; called by muse, mutect2, varscan2
- PER3 | c.2477G>T p.G826V | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT tolerated (0.27); PolyPhen benign (0.302); catalogued as COSV62707288; called by muse, mutect2, varscan2
- PHLDB1 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as rs1335062695; called by muse, mutect2, varscan2
- PLAGL1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 228/246 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780760124; called by mutect2, varscan2
- PLAGL2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs757572858; called by muse, mutect2, varscan2
- PLCG1 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs761490511, COSV54824854; called by muse, mutect2, varscan2
- PLCXD2 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.644); catalogued as rs773816416; called by muse, varscan2
- PLXNA2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 76/86 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1474889326; called by muse, mutect2, varscan2
- PLXNB3 | c.5032C>T p.R1678W | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782236615, COSV62796317; called by muse, mutect2, varscan2
- PNPLA7 | c.2683A>G p.K895E | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs534417123; called by muse, mutect2, varscan2
- POLE | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs878854842, COSV57678756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLM | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 131/222 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1222972213; called by muse, mutect2, varscan2
- POU2AF1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs1479184952; called by muse, mutect2, varscan2
- POU2F3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1329091022, COSV52792295; called by muse, mutect2
- PPARGC1A | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539338812, COSV53524913; called by muse, mutect2, varscan2
- PRSS8 | c.124del p.Q42Kfs*64 | Frame Shift Del (DEL) | VAF 112/244 reads (46%) | catalogued as COSV99571515; called by mutect2, pindel, varscan2
- PXDC1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 77/83 reads (93%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.767); catalogued as rs1283560756, COSV66661360; called by muse, mutect2, varscan2
- RABGAP1 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767593775, COSV65380148; called by muse, mutect2, varscan2
- RANBP10 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs763086072, COSV58156594; called by muse, mutect2, varscan2
- RASSF5 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 115/133 reads (86%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as rs570039354, COSV58798296; called by muse, mutect2, varscan2
- RECQL4 | c.3532G>A p.G1178R | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776146178, COSV100020196, COSV56740677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOF | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746745426, COSV57363206; called by muse, mutect2, varscan2
- RNF130 | c.948G>A p.P316= | Splice Region (SNP) | VAF 55/119 reads (46%) | catalogued as rs577094030, COSV56150982; called by muse, mutect2, varscan2
- RPH3AL | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs758943991, COSV58745184; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 16/20 reads (80%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS3 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 143/162 reads (88%) | SIFT tolerated (0.73); PolyPhen benign (0.02); catalogued as COSV53704866; called by muse, mutect2, varscan2
- RRP12 | c.2872G>A p.V958M | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs370226569; called by muse, mutect2, varscan2
- SAMD15 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs758128789, COSV53626140; called by muse, mutect2, varscan2
- SBK2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749649082, COSV60015976; called by muse, mutect2, varscan2
- SCAF4 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV54584382; called by muse, mutect2, varscan2
- SCAP | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 71/83 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208071175, COSV55560884; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 47/90 reads (52%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3G | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 137/145 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs751358507; called by muse, mutect2, varscan2
- SIN3B | c.2791G>A p.V931I | Missense Mutation (SNP) | VAF 122/235 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.707); catalogued as rs748832527, COSV56131573; called by muse, mutect2, varscan2
- SLC2A13 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55114228; called by muse, mutect2, varscan2
- SLC38A9 | c.1113del p.F371Lfs*10 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs746769804; called by mutect2, pindel, varscan2
- SLC5A9 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1323631952, COSV99361656; called by muse, mutect2
- SLC9A9 | c.1700A>G p.Q567R | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs374325238; called by muse, mutect2, varscan2
- SLIT2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1373460019, COSV56569954, COSV56594632, COSV56596873; called by muse, mutect2
- SNRNP35 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1018615078, COSV100644542; called by muse, mutect2
- SORCS2 | c.3337G>A p.A1113T | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs753839524; called by muse, mutect2, varscan2
- SPRING1 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs149801903; called by muse, mutect2, varscan2
- SRPK1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 68/81 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs1277363881, COSV60410831; called by muse, mutect2, varscan2
- SRRM1 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.034); catalogued as rs370225206; called by muse, mutect2, varscan2
- SUFU | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs773037813, COSV104425314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT17 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs371789759; called by muse, varscan2
- TET3 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs757324110; called by muse, mutect2, varscan2
- TEX11 | c.1090C>T p.R364C (on ENST00000344304; = p.R349C on NM_031276.3) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs773463882, COSV60229606; called by muse, mutect2, varscan2
- TFDP1 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs760185871, COSV64739814; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs754390908; called by mutect2, varscan2
- TMC6 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs150505551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMCC1 | c.1748G>A p.R583Q (on ENST00000393238 / NM_001349268.2; = p.R259Q on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/138 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1288910841; called by muse, mutect2, varscan2
- TMEM132D | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV70600989, COSV70613616; called by muse, mutect2, varscan2
- TMEM231 | c.673G>A p.V225I (on ENST00000258173 / NM_001077418.3; = p.V254I on NM_001077416.2) | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs746055228, COSV50738885; called by muse, mutect2, varscan2
- TMTC2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs1270709596, COSV58281131; called by muse, mutect2, varscan2
- TRIM54 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 108/121 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs988891315, COSV56079683; called by muse, mutect2, varscan2
- TRPC7 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1397447321, COSV61457798; called by muse, mutect2
- TSC22D1 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs949837727; called by muse, mutect2
- TTC21A | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 86/98 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369092746; called by muse, mutect2, varscan2
- UNC5D | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 137/206 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1368009647, COSV99779463; called by muse, mutect2, varscan2
- USP21 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs746631922; called by muse, mutect2, varscan2
- USP34 | c.2440T>C p.S814P | Missense Mutation (SNP) | VAF 183/211 reads (87%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as COSV101277230; called by muse, mutect2, varscan2
- USP54 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs150999517; called by muse, mutect2, varscan2
- UVSSA | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762685790; called by muse, varscan2
- VARS1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 112/129 reads (87%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as rs1346037848; called by muse, mutect2, varscan2
- VAV1 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.847); catalogued as rs1172825998, COSV100409033, COSV58387057; called by muse, mutect2, varscan2
- VMO1 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.454); catalogued as rs770901607; called by muse, mutect2, varscan2
- VPS13A | c.5036C>T p.T1679M | Missense Mutation (SNP) | VAF 103/112 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0.148); catalogued as rs144009026; called by muse, mutect2, varscan2
- VWA5A | c.887T>C p.M296T | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as rs766258808; called by muse, mutect2, varscan2
- WNK4 | c.3496C>T p.R1166W | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770685193, COSV55903374; called by muse, varscan2
- ZC3H4 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs1043772363, COSV53415319; called by muse, mutect2, varscan2
- ZDHHC5 | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.951); catalogued as rs567126462, COSV54705237; called by muse, mutect2, varscan2
- ZFP28 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as rs139300625; called by muse, mutect2, varscan2
- ZNF419 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.175); catalogued as COSV55660337; called by muse, mutect2, varscan2
- ZNF425 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV65201317, COSV65202753; called by muse, mutect2, varscan2
- ZNF652 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 112/205 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs779533531, COSV62946159; called by muse, mutect2, varscan2
- ZNF781 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.11); catalogued as rs12460961, COSV62201255; called by muse, mutect2, varscan2
- ZNRF3 | c.919C>T p.R307W (on ENST00000544604 / NM_001206998.2; = p.R207W on NM_032173.3) | Missense Mutation (SNP) | VAF 134/151 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60431866; called by muse, mutect2, varscan2
- ZSCAN18 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs73058515, COSV53729581; called by muse, varscan2
- ZSCAN20 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs765255696, COSV63682117, COSV63683403; called by muse, mutect2, varscan2
- ACACB | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AKAP12 | c.2844del p.T949Rfs*23 | Frame Shift Del (DEL) | VAF 24/38 reads (63%) | called by mutect2, pindel, varscan2
- ARHGEF10L | c.2489del p.G830Afs*15 | Frame Shift Del (DEL) | VAF 72/106 reads (68%) | called by mutect2, pindel, varscan2
- ASMTL | c.1826del p.G609Vfs*22 | Frame Shift Del (DEL) | VAF 106/295 reads (36%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.1371G>A p.L457= | Splice Region (SNP) | VAF 125/246 reads (51%) | called by muse, varscan2
- BCORL1 | c.2306del p.K769Rfs*14 | Frame Shift Del (DEL) | VAF 122/132 reads (92%) | called by mutect2, varscan2
- BOP1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.53); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- BRWD1 | c.532del p.M178Cfs*15 | Frame Shift Del (DEL) | VAF 72/107 reads (67%) | called by mutect2, pindel, varscan2
- C1QTNF2 | c.246C>G p.S82R (on ENST00000393975; = p.S37R on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CACNA1A | c.4948G>A p.V1650M | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CACNA1A | c.4353G>T p.W1451C | Missense Mutation (SNP) | VAF 103/198 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CAPN6 | c.340dup p.T114Nfs*20 | Frame Shift Ins (INS) | VAF 44/64 reads (69%) | called by mutect2, pindel, varscan2
- DDX6 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- DNAH11 | c.3824C>T p.A1275V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- EML2 | c.710del p.G237Afs*3 | Frame Shift Del (DEL) | VAF 45/128 reads (35%) | called by mutect2, pindel, varscan2
- EPB41L1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESF1 | c.2514_2515del p.K838Nfs*23 | Frame Shift Del (DEL) | VAF 32/50 reads (64%) | called by mutect2, pindel, varscan2
- FGFR4 | c.1251+3A>G | Splice Region (SNP) | VAF 52/138 reads (38%) | called by muse, mutect2, varscan2
- FRYL | c.4273_4275del p.K1425del | In Frame Del (DEL) | VAF 26/85 reads (31%) | called by pindel, varscan2
- GDAP2 | c.840_843del p.F281Lfs*19 | Frame Shift Del (DEL) | VAF 41/47 reads (87%) | called by mutect2, pindel, varscan2
- GPR162 | c.909del p.W304Gfs*82 (on ENST00000311268 / NM_019858.2; = p.W20Gfs*82 on NM_014449.2) | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- HIP1R | c.978dup p.A327Rfs*9 | Frame Shift Ins (INS) | VAF 47/157 reads (30%) | called by mutect2, pindel, varscan2
- IGSF10 | c.3041G>T p.R1014M | Missense Mutation (SNP) | VAF 62/70 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- INPP5F | c.2596A>G p.N866D | Missense Mutation (SNP) | VAF 99/166 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- INTS4 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 92/241 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); called by muse, varscan2
- KDM7A | c.1217T>C p.V406A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 49/110 reads (45%) | called by mutect2, pindel, varscan2
- LDHA | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- LHX1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 159/177 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGI1 | c.2908G>A p.D970N (on ENST00000402939 / NM_001033057.2; = p.D998N on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- MBTPS1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MYBL2 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 125/131 reads (95%) | called by muse, mutect2, varscan2
- MYNN | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NKAP | c.1192del p.L398Wfs*67 | Frame Shift Del (DEL) | VAF 68/100 reads (68%) | called by mutect2, pindel, varscan2
- NRXN1 | c.4259A>T p.Y1420F | Missense Mutation (SNP) | VAF 132/151 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, varscan2
- NUP205 | c.5306T>C p.L1769S | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NXPE3 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, varscan2
- OR51F2 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- PDZD7 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); called by muse, mutect2
- PHF20L1 | c.893del p.K298Rfs*66 | Frame Shift Del (DEL) | VAF 37/72 reads (51%) | called by mutect2, pindel, varscan2
- PIK3R2 | c.1792A>G p.K598E | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POLA2 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PSMC1 | c.410_414del p.S137Cfs*28 | Frame Shift Del (DEL) | VAF 60/259 reads (23%) | called by mutect2, pindel, varscan2
- PWWP2B | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 91/142 reads (64%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, varscan2
- SCYL2 | c.2632G>T p.G878C | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.417); called by muse, mutect2
- SLC25A52 | c.386C>T p.A129V (on ENST00000672005; = p.A119V on NM_001034172.4) | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- SLITRK3 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 46/51 reads (90%) | called by muse, mutect2, varscan2
- SMARCD3 | c.865C>T p.Q289* (on ENST00000262188 / NM_001003801.2; = p.Q276* on NM_003078.4) | Nonsense Mutation (SNP) | VAF 41/179 reads (23%) | called by muse, mutect2, varscan2
- SPATA13 | c.288C>T p.N96= | Splice Region (SNP) | VAF 51/61 reads (84%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, varscan2
- TENM2 | c.4171G>A p.G1391S (on ENST00000518659 / NM_001122679.2; = p.G1152S on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- TJP2 | c.2567-2A>G p.X856_splice | Splice Site (SNP) | VAF 86/87 reads (99%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TNRC6B | c.1409del p.N470Mfs*33 | Frame Shift Del (DEL) | VAF 39/62 reads (63%) | called by mutect2, pindel, varscan2
- UBE3C | c.2002G>A p.V668M | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- UBE4B | c.2264C>T p.T755M (on ENST00000343090 / NM_001105562.3; = p.T626M on NM_006048.5) | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBQLN2 | c.1574del p.P525Lfs*71 | Frame Shift Del (DEL) | VAF 40/46 reads (87%) | called by mutect2, varscan2
- UNC5D | c.1709C>G p.A570G | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VDR | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 207/420 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- YPEL2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 105/116 reads (91%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ZNF429 | c.1807A>C p.N603H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ZSWIM8 | c.1943C>A p.P648H | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC12 | c.1635C>T p.Y545= | Silent (SNP) | VAF 85/164 reads (52%) | catalogued as rs764643104; called by muse, mutect2, varscan2
- ABCC4 | c.1314C>T p.G438= | Silent (SNP) | VAF 86/97 reads (89%) | catalogued as rs150945397; called by muse, mutect2, varscan2
- ACSBG1 | c.1983C>T p.I661= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs748164226; called by muse, mutect2, varscan2
- AKAP6 | c.678A>G p.E226= | Silent (SNP) | VAF 173/391 reads (44%) | called by muse, mutect2, varscan2
- ANK1 | c.2268C>T p.N756= | Silent (SNP) | VAF 55/92 reads (60%) | catalogued as rs759268149, COSV55899125; called by muse, mutect2, varscan2
- ANKRD11 | c.807G>A p.T269= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as rs149525788, COSV56366831; called by muse, mutect2, varscan2
- ATP1A2 | c.1581C>T p.L527= | Silent (SNP) | VAF 56/60 reads (93%) | catalogued as rs371520433, COSV63404796; called by muse, mutect2, varscan2
- ATP1B4 | c.897C>T p.Y299= (on ENST00000218008 / NM_001142447.3; = p.Y295= on NM_012069.5) | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs148650396, COSV54311543; called by muse, mutect2, varscan2
- ATP2B4 | c.2262G>A p.A754= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs750641764, COSV58176535; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1824C>T p.H608= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as rs549185406; called by muse, mutect2, varscan2
- BAIAP2 | c.162C>T p.D54= | Silent (SNP) | VAF 17/19 reads (89%) | catalogued as rs758411223; called by muse, mutect2, varscan2
- BICRA | c.3621G>A p.S1207= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs747734032; called by muse, mutect2, varscan2
- BRINP2 | c.897C>T p.C299= | Silent (SNP) | VAF 165/371 reads (44%) | called by muse, mutect2, varscan2
- C1R | c.2031G>A p.P677= (on ENST00000536053 / NM_001354346.2; = p.P663= on NM_001733.7) | Silent (SNP) | VAF 45/186 reads (24%) | catalogued as rs147540938; called by muse, mutect2, varscan2
- CAMSAP3 | c.3732C>T p.G1244= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1237277158, COSV50340180; called by muse, mutect2
- CLPTM1L | c.477G>A p.P159= | Silent (SNP) | VAF 148/295 reads (50%) | catalogued as rs376216239; called by muse, mutect2, varscan2
- CRTC3 | c.1611G>A p.P537= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs370456941; called by muse, mutect2, varscan2
- CSF1 | c.1593G>A p.A531= | Silent (SNP) | VAF 60/148 reads (41%) | catalogued as rs376460825; called by muse, mutect2, varscan2
- CSMD1 | c.5238C>T p.P1746= (on ENST00000520002; = p.P1745= on NM_033225.6) | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as rs1474815603; called by muse, mutect2, varscan2
- CUBN | c.4959G>A p.A1653= | Silent (SNP) | VAF 56/174 reads (32%) | catalogued as rs577984421, COSV100913637, COSV64716458; called by muse, mutect2, varscan2
- EFS | c.708C>T p.P236= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs780903931, COSV53733415; called by muse, mutect2, varscan2
- EIF4G3 | c.603C>T p.S201= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs372335024; called by muse, mutect2, varscan2
- FASTKD5 | c.2259G>A p.A753= | Silent (SNP) | VAF 105/119 reads (88%) | catalogued as rs762402996; called by muse, varscan2
- FBXW9 | c.642C>T p.T214= (on ENST00000587955; = p.T224= on NM_032301.3) | Silent (SNP) | VAF 114/231 reads (49%) | called by muse, mutect2, varscan2
- FIBCD1 | c.723C>T p.P241= | Silent (SNP) | VAF 276/295 reads (94%) | called by muse, mutect2, varscan2
- FNDC7 | c.1788C>T p.C596= | Silent (SNP) | VAF 8/133 reads (6%) | catalogued as rs1336120719; called by muse, mutect2
- GHITM | c.708G>A p.A236= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as rs201995209; called by muse, mutect2, varscan2
- GRIP2 | c.2211C>T p.D737= (on ENST00000619221; = p.D640= on NM_001080423.4) | Silent (SNP) | VAF 69/81 reads (85%) | catalogued as rs367789595; called by muse, mutect2, varscan2
- GUCY1B1 | c.51C>T p.Y17= | Silent (SNP) | VAF 114/223 reads (51%) | catalogued as rs372884496; called by muse, mutect2, varscan2
- HMOX2 | c.621C>T p.N207= | Silent (SNP) | VAF 269/664 reads (41%) | catalogued as rs186971432; called by muse, varscan2
- HTR2C | c.603C>T p.F201= | Silent (SNP) | VAF 85/231 reads (37%) | catalogued as COSV52201965; called by muse, mutect2, varscan2
- HTR3A | c.1257G>T p.L419= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- IKZF3 | c.717G>T p.A239= | Silent (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- ITSN1 | c.3492C>T p.Y1164= | Silent (SNP) | VAF 70/160 reads (44%) | catalogued as rs1439468784, COSV66082854; called by muse, mutect2, varscan2
- JADE2 | c.558T>C p.I186= | Silent (SNP) | VAF 53/400 reads (13%) | called by muse, varscan2
- JADE2 | c.606C>T p.C202= | Silent (SNP) | VAF 224/448 reads (50%) | catalogued as rs748101325, COSV50917166; called by muse, varscan2
- KANK1 | c.3507C>T p.S1169= | Silent (SNP) | VAF 51/254 reads (20%) | catalogued as rs1261505374, COSV100619729; called by muse, mutect2, varscan2
- KCTD21 | c.435C>T p.N145= | Silent (SNP) | VAF 64/76 reads (84%) | catalogued as rs766255208, COSV60741122; called by muse, mutect2, varscan2
- KIAA1614 | c.3330C>T p.D1110= | Silent (SNP) | VAF 40/46 reads (87%) | catalogued as rs369477801; called by muse, varscan2
- LCMT1 | c.384G>A p.T128= | Silent (SNP) | VAF 59/135 reads (44%) | called by muse, mutect2, varscan2
- LCOR | c.102G>A p.P34= | Silent (SNP) | VAF 48/76 reads (63%) | catalogued as rs1304914442, COSV63630206; called by muse, mutect2, varscan2
- LRP4 | c.1584C>T p.T528= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs574108233; called by muse, mutect2, varscan2
- MCF2L | c.2595C>T p.H865= (on ENST00000375608; = p.H833= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/322 reads (18%) | catalogued as rs746413581; called by muse, mutect2, varscan2
- MICAL2 | c.768G>A p.A256= | Silent (SNP) | VAF 89/90 reads (99%) | catalogued as rs138615174; called by muse, mutect2, varscan2
- MROH1 | c.2577C>T p.D859= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as rs993476172; called by muse, mutect2, varscan2
- MROH6 | c.612C>T p.A204= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs541151034; called by muse, mutect2, varscan2
- MYO10 | c.3423G>A p.A1141= | Silent (SNP) | VAF 118/262 reads (45%) | catalogued as rs150139256; called by muse, varscan2
- MYO1C | c.2766G>A p.A922= (on ENST00000648651 / NM_001080779.2; = p.A887= on NM_033375.5) | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs778887409; called by muse, mutect2, varscan2
- NEXMIF | c.2868C>T p.T956= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV50097854; called by muse, mutect2
- NUMA1 | c.5241C>T p.D1747= | Silent (SNP) | VAF 47/49 reads (96%) | catalogued as rs575875975; called by muse, mutect2, varscan2
- NXPE4 | c.438G>A p.A146= | Silent (SNP) | VAF 108/217 reads (50%) | catalogued as rs752391000, COSV64943364; called by muse, varscan2
- OGDH | c.2802G>A p.S934= | Silent (SNP) | VAF 63/103 reads (61%) | catalogued as rs778413428; called by muse, mutect2, varscan2
- OPRK1 | c.558G>A p.S186= | Silent (SNP) | VAF 63/198 reads (32%) | catalogued as rs200269505, COSV55570013; called by muse, mutect2, varscan2
- OR8S1 | c.1017G>A p.T339= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1379039229, COSV59600462; called by muse, mutect2, varscan2
- PA2G4 | c.831G>A p.P277= | Silent (SNP) | VAF 73/152 reads (48%) | catalogued as rs145895424; called by muse, mutect2, varscan2
- PAPSS2 | c.132C>T p.T44= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs753690800; called by muse, mutect2, varscan2
- PCDH18 | c.3177T>C p.S1059= | Silent (SNP) | VAF 94/244 reads (39%) | called by muse, mutect2, varscan2
- PCDHB5 | c.660G>A p.P220= | Silent (SNP) | VAF 48/180 reads (27%) | called by muse, varscan2
- PCDHGC4 | c.369C>T p.I123= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as rs1040028231, COSV52770997; called by muse, mutect2
- PCNX1 | c.6438G>A p.V2146= | Silent (SNP) | VAF 57/264 reads (22%) | catalogued as COSV53104063; called by muse, mutect2, varscan2
- PELI3 | c.870C>T p.D290= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs756018771; called by muse, mutect2
- PFKL | c.810C>T p.N270= | Silent (SNP) | VAF 61/171 reads (36%) | catalogued as rs749333614; called by muse, mutect2, varscan2
- PKD2 | c.2667C>T p.A889= | Silent (SNP) | VAF 71/271 reads (26%) | catalogued as rs747027723, COSV52937770; called by muse, mutect2, varscan2
- PLCD4 | c.1554C>T p.Y518= | Silent (SNP) | VAF 50/59 reads (85%) | catalogued as rs374723132; called by muse, mutect2, varscan2
- PLEKHG5 | c.564T>C p.P188= (on ENST00000400915 / NM_001042663.3; = p.P151= on NM_020631.6) | Silent (SNP) | VAF 38/51 reads (75%) | called by muse, mutect2, varscan2
- PPP1R13B | c.2640C>T p.H880= | Silent (SNP) | VAF 77/147 reads (52%) | catalogued as rs1376023409, COSV52452844; called by muse, mutect2, varscan2
- PRPS1 | c.789C>T p.N263= | Silent (SNP) | VAF 95/199 reads (48%) | catalogued as rs1210109668, COSV65054381; called by muse, mutect2, varscan2
- PTPRS | c.5820C>T p.L1940= | Silent (SNP) | VAF 47/203 reads (23%) | catalogued as rs756783819; called by muse, mutect2, varscan2
- RBM33 | c.2232G>A p.S744= | Silent (SNP) | VAF 74/309 reads (24%) | catalogued as rs762394522; called by muse, mutect2, varscan2
- REEP6 | c.414C>T p.R138= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs1473647583, COSV52014247; called by muse, mutect2, varscan2
- RET | c.3093C>T p.D1031= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs369116900; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RRP12 | c.1062C>T p.H354= | Silent (SNP) | VAF 139/228 reads (61%) | catalogued as rs377580724; called by muse, mutect2, varscan2
- RYR1 | c.7827G>A p.S2609= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs201827284; ClinVar: likely benign; called by muse, varscan2
- SIPA1L3 | c.1878C>T p.G626= | Silent (SNP) | VAF 31/163 reads (19%) | called by muse, mutect2, varscan2
- SLC35C1 | c.996C>T p.G332= | Silent (SNP) | VAF 44/46 reads (96%) | catalogued as rs144046143; called by muse, mutect2, varscan2
- SLC36A4 | c.1254C>T p.F418= | Silent (SNP) | VAF 125/134 reads (93%) | catalogued as rs267603248, COSV58396093; called by muse, mutect2, varscan2
- SLC9A1 | c.1695C>T p.G565= | Silent (SNP) | VAF 57/61 reads (93%) | catalogued as rs144261466; called by muse, mutect2, varscan2
- SMARCAL1 | c.1530C>T p.N510= | Silent (SNP) | VAF 146/166 reads (88%) | catalogued as rs773199821, COSV61919735; called by muse, varscan2
- SORBS3 | c.714G>A p.T238= | Silent (SNP) | VAF 96/148 reads (65%) | catalogued as rs201952170, COSV53552902; called by muse, mutect2, varscan2
- SPATS2L | c.1455C>T p.G485= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs867034558; called by muse, mutect2, varscan2
- SPINDOC | c.945G>A p.P315= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs777393735; called by muse, mutect2, varscan2
- STRADA | c.1281C>T p.D427= (on ENST00000336174 / NM_001363786.1; = p.D390= on NM_001003786.3) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs758494527, COSV51991352; called by muse, mutect2, varscan2
- SYBU | c.1263G>A p.T421= (on ENST00000276646 / NM_001099754.2; = p.T420= on NM_017786.6) | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs750027113, COSV52616462; called by muse, mutect2, varscan2
- SYNE2 | c.17523C>T p.H5841= | Silent (SNP) | VAF 104/222 reads (47%) | catalogued as rs202141038; ClinVar: likely benign; called by muse, mutect2, varscan2
- TECPR1 | c.2652G>A p.T884= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as rs756007207; called by muse, mutect2, varscan2
- TMEM8B | c.1353C>T p.N451= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as rs780799345, COSV100941714; called by muse, varscan2
- TPM3 | c.831C>T p.H277= | Silent (SNP) | VAF 74/149 reads (50%) | catalogued as rs781032589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRRAP | c.11328C>T p.D3776= (on ENST00000359863 / NM_001244580.1; = p.D3747= on NM_003496.3) | Silent (SNP) | VAF 72/216 reads (33%) | catalogued as rs548877968; called by muse, mutect2, varscan2
- VLDLR | c.636C>T p.C212= | Silent (SNP) | VAF 71/281 reads (25%) | catalogued as rs758704925, COSV101173223; called by muse, mutect2, varscan2
- WDR1 | c.1029C>T p.D343= (on ENST00000382452; = p.D203= on NM_005112.5) | Silent (SNP) | VAF 50/301 reads (17%) | catalogued as rs763307377; called by muse, mutect2, varscan2
- WNK2 | c.2415G>A p.T805= | Silent (SNP) | VAF 34/263 reads (13%) | catalogued as rs753283002, COSV99943399; called by muse, mutect2, varscan2
- WNT5B | c.297C>T p.N99= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs777122670, COSV60198027; called by muse, mutect2, varscan2
- ZC3H14 | c.1705C>T p.L569= | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as rs770659304; called by muse, mutect2, varscan2
- ZFPM2 | c.2688G>A p.P896= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1434631824, COSV101023046, COSV65872516; called by muse, mutect2
- ZNF264 | c.1281C>T p.F427= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as rs748919450, COSV54040702; called by muse, mutect2, varscan2
- ZNF473 | c.975C>T p.C325= | Silent (SNP) | VAF 103/214 reads (48%) | catalogued as rs146105171; called by muse, mutect2, varscan2
- ZNF665 | c.1356T>C p.N452= (on ENST00000600412; = p.N517= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 79/140 reads (56%) | called by muse, mutect2, varscan2
- ZNF701 | c.942C>T p.C314= (on ENST00000301093; = p.C248= on NM_018260.3) | Silent (SNP) | VAF 171/347 reads (49%) | catalogued as rs936069590, COSV56525709; called by muse, mutect2, varscan2
- ZNF836 | c.1959A>G p.L653= | Silent (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2
- AL590867.2 | n.287G>A | RNA (SNP) | VAF 64/73 reads (88%) | called by muse, mutect2, varscan2
- C1QTNF3 | c.84+66C>T | Intron (SNP) | VAF 77/152 reads (51%) | catalogued as rs143587337, COSV99180714; called by muse, mutect2, varscan2
- DOT1L | c.4606+947G>A | Intron (SNP) | VAF 56/115 reads (49%) | catalogued as rs1309043428; called by muse, mutect2, varscan2
- ERAL1 | chr17:28861543 G>A | 3'Flank (SNP) | VAF 32/93 reads (34%) | catalogued as rs774580747; called by muse, mutect2, varscan2
- ERMN | c.-17G>A | 5'UTR (SNP) | VAF 6/82 reads (7%) | catalogued as rs1240881527, COSV68075263; called by muse, mutect2
- MACF1 | c.15832-11390T>C | Intron (SNP) | VAF 73/95 reads (77%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-7918C>T | Intron (SNP) | VAF 110/128 reads (86%) | catalogued as rs760762570; called by muse, mutect2, varscan2
- MBD1 | c.*121C>A | 3'UTR (SNP) | VAF 48/132 reads (36%) | called by muse, mutect2, varscan2
- RRN3 | c.*1C>T | 3'UTR (SNP) | VAF 31/148 reads (21%) | catalogued as rs750032752; called by muse, mutect2, varscan2
